Somatic mutation profile of tumor specimen TCGA-UU-A93S-01A (aliquot TCGA-UU-A93S-01A-21D-A41F-09) from TCGA case TCGA-UU-A93S, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.7 years (23,278 days).
Specimen TCGA-UU-A93S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b616505-ec4d-4d8c-af44-4a2dc25c31b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UU-A93S-10A (Blood Derived Normal), aliquot TCGA-UU-A93S-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e4c4198-4a60-452d-be13-5b4d0a4a20c7

The open-access MAF lists 146 somatic variants for this specimen: 111 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1, Nonstop Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1135401757, COSV99332265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567554216, COSV52751724, COSV52782611, COSV52910696, COSV53122800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as COSV101002033, COSV65892039; called by muse, mutect2, varscan2
- AJAP1 | c.750del p.S251Afs*44 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as COSV65451938; called by mutect2, pindel, varscan2
- AMER3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs374506642, COSV100365960; called by muse, mutect2, varscan2
- ANKK1 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100392691, COSV58273586; called by muse, mutect2, varscan2
- ANKRD28 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV101080291; called by muse, mutect2, varscan2
- ANOS1 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV99390438; called by muse, mutect2, varscan2
- ATR | c.3575G>A p.C1192Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100637674; called by muse, mutect2, varscan2
- BAX | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as rs202190487, COSV53169117, COSV53170003; called by muse, mutect2, varscan2
- BAZ2A | c.1765C>A p.Q589K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99464762; called by muse, mutect2, varscan2
- BORA | c.1096+1G>A p.X366_splice (on ENST00000613797; = p.X291_splice on NM_024808.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100909641; called by muse, mutect2, varscan2
- CAMK2B | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.027); catalogued as COSV99322758; called by muse, mutect2, varscan2
- CAPRIN2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV51834479, COSV99195414; called by muse, mutect2
- CATSPER4 | c.1338G>T p.L446F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100128197; called by muse, mutect2
- CCDC65 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99872681; called by muse, mutect2, varscan2
- CDKL3 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443898936, COSV54744373; called by muse, mutect2, varscan2
- COL12A1 | c.7160C>A p.A2387D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100485408; called by muse, mutect2
- COL20A1 | c.2083G>T p.V695F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100489930; called by muse, mutect2, varscan2
- COL4A4 | c.4705T>A p.C1569S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306220; called by muse, mutect2, varscan2
- CPEB2 | c.2737C>A p.P913T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52591479, COSV99469932; called by muse, mutect2, varscan2
- CPXM2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as rs1279879025, COSV99581104; called by muse, mutect2, varscan2
- CPZ | c.397T>A p.F133I (on ENST00000360986 / NM_001014447.3; = p.F122I on NM_003652.3) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100248756; called by muse, mutect2, varscan2
- CR2 | c.549T>G p.C183W | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889531; called by muse, mutect2, varscan2
- DENND1B | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99343779; called by muse, mutect2, varscan2
- DOCK11 | c.6200C>A p.S2067Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV99352909; called by muse, mutect2, varscan2
- EPHX3 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV99691457; called by muse, mutect2, varscan2
- FAM83G | c.2187C>A p.S729R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100524812, COSV100525138; called by muse, mutect2
- FAM90A1 | c.872A>T p.K291M | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100274183; called by muse, mutect2, varscan2
- FLNC | c.3309C>A p.C1103* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as COSV100367633; called by muse, mutect2
- FNDC3B | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs1560082057, COSV100393616; called by muse, mutect2, varscan2
- FRAS1 | c.9428G>T p.G3143V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99348296; called by muse, mutect2, varscan2
- FREM2 | c.8854A>G p.I2952V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.54); catalogued as COSV99746844; called by muse, mutect2, varscan2
- FUS | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99568290, COSV99568347; called by muse, mutect2, varscan2
- GANC | c.2229G>T p.E743D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | PolyPhen benign (0.147); catalogued as COSV100530680; called by muse, mutect2
- GBE1 | c.123C>G p.Y41* | Nonsense Mutation (SNP) | VAF 57/123 reads (46%) | catalogued as COSV101450078; called by muse, mutect2, varscan2
- GFAP | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs1364674732, COSV99493062; called by muse, mutect2, varscan2
- H2BC14 | c.109A>T p.S37C | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); catalogued as COSV100297483; called by muse, mutect2, varscan2
- HECW1 | c.2588C>G p.A863G | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV101222821; called by muse, mutect2
- HIPK3 | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs748963286, COSV100305399; called by muse, mutect2, varscan2
- IL16 | c.3370C>G p.L1124V (on ENST00000302987 / NM_172217.5; = p.L423V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100266989; called by muse, mutect2, varscan2
- ITIH4 | c.1171+1G>A p.X391_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as rs925188733, COSV99818900; called by muse, mutect2, varscan2
- ITPR3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100966926; called by muse, mutect2
- KDM6A | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100937902, COSV65038316, COSV65045261; called by muse, mutect2, varscan2
- KLHL1 | c.2040G>A p.W680* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100917011; called by muse, mutect2, varscan2
- KRTAP6-3 | c.272_274del p.F91del | In Frame Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs1442844739; called by mutect2, pindel, varscan2
- LCN1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55017577; called by muse, mutect2, varscan2
- LTBP4 | c.1675G>T p.G559* (on ENST00000308370 / NM_001042544.1; = p.G522* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99180425; called by muse, mutect2, varscan2
- MACF1 | c.6572A>T p.E2191V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99241225; called by muse, mutect2, varscan2
- MAD1L1 | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99765129; called by muse, mutect2, varscan2
- MDC1 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1381054079, COSV64528691; called by muse, mutect2
- MEGF8 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as rs555480088, COSV99234466; called by muse, mutect2, varscan2
- MFN1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs774808113, COSV54941687; called by muse, mutect2, varscan2
- MIA3 | c.5117C>G p.S1706* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100484802; called by muse, mutect2
- MICAL3 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99259939; called by muse, varscan2
- MYO7B | c.6332C>A p.P2111Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100264176; called by muse, mutect2
- NLRP4 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100015604, COSV56711001; called by muse, mutect2, varscan2
- NSMAF | c.2597G>C p.G866A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232348; called by muse, mutect2, varscan2
- OBI1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99932282; called by muse, mutect2, varscan2
- OR11L1 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs773344770, COSV100869383; called by muse, varscan2
- OR9G4 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100264997; called by muse, mutect2, varscan2
- PCDHB10 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.934); catalogued as COSV99503670; called by muse, mutect2, varscan2
- PEAK1 | c.4957C>T p.R1653W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158393761, COSV56939832; called by muse, mutect2, varscan2
- PHACTR1 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100275509; called by muse, mutect2, varscan2
- PHOX2B | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99890824; called by muse, mutect2, varscan2
- PPP1CC | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58585033; called by muse, mutect2, varscan2
- PPP1R3A | c.3369A>T p.*1123Yext*21 | Nonstop Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99491959; called by muse, mutect2, varscan2
- PRDM10 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs757261827, COSV100456562; called by muse, varscan2
- PRKAA1 | c.1502G>C p.R501P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.572); catalogued as rs369722345; called by muse, mutect2, varscan2
- PTCHD3 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101438821, COSV71257264; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 118/148 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52864258, COSV99228648; called by muse, mutect2, varscan2
- RASGRP1 | c.1915G>C p.V639L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100171738; called by muse, mutect2, varscan2
- RBM26 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99935795; called by muse, mutect2, varscan2
- RELN | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs370745351; called by muse, mutect2, varscan2
- REXO1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs774162601, COSV99402008; called by muse, mutect2, varscan2
- RFX5 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100923823; called by muse, mutect2
- RGS12 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750469659, COSV100374761; called by muse, mutect2, varscan2
- RYR3 | c.8794G>T p.A2932S (on ENST00000389232; = p.A2933S on NM_001036.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as rs1458988005, COSV101212006, COSV66779054; called by muse, varscan2
- SAMD10 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53878278, COSV99411351; called by muse, mutect2, varscan2
- SAV1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 37/54 reads (69%) | catalogued as COSV100220628; called by muse, mutect2, varscan2
- SBNO2 | c.2613G>C p.K871N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100684094; called by muse, mutect2, varscan2
- SCN3A | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs965476894, COSV51822082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFI1 | c.3205G>C p.G1069R (on ENST00000400288 / NM_001007467.3; = p.G1038R on NM_014775.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs771038010, COSV99837162; called by muse, mutect2, varscan2
- SLC16A2 | c.1615A>C p.I539L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV99330376; called by muse, mutect2, varscan2
- SLC35C2 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99709042; called by muse, mutect2, varscan2
- SLC9A8 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779814701, COSV64288462; called by muse, mutect2, varscan2
- SLCO6A1 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101133992; called by muse, mutect2, varscan2
- SNUPN | c.1008G>T p.L336F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100419285; called by muse, mutect2, varscan2
- SOX6 | c.1841G>T p.R614L (on ENST00000528429 / NM_001145819.2; = p.R587L on NM_017508.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1242397325, COSV100321255, COSV57053359; called by muse, mutect2, varscan2
- SPPL3 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.943); catalogued as COSV100793552; called by muse, mutect2, varscan2
- TEDC1 | c.1052C>G p.P351R (on ENST00000392523 / NM_001367178.1; = p.P282R on NM_001134875.1) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV100321996; called by muse, mutect2, varscan2
- TENM1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100949066; called by muse, mutect2, varscan2
- TPM3 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs769493959, COSV99666051; called by muse, mutect2, varscan2
- TRBV29-1 | c.129A>C p.Q43H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1235618777; called by muse, mutect2, varscan2
- TRIM51 | c.998C>G p.A333G | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV99792142; called by muse, mutect2, varscan2
- TTN | c.96922A>T p.T32308S (on ENST00000591111; = p.T24884S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | PolyPhen possibly damaging (0.585); catalogued as COSV100594483; called by muse, mutect2, varscan2
- TUBB2A | c.1209G>C p.M403I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100373759; called by muse, mutect2, varscan2
- UBOX5 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV53906089, COSV99417396; called by muse, mutect2
- UHRF1BP1 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV99511464; called by muse, mutect2
- ZDHHC15 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100973649; called by muse, mutect2, varscan2
- ZEB1 | c.2527T>C p.Y843H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100313643; called by muse, mutect2, varscan2
- ZNF468 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99700336; called by muse, mutect2, varscan2
- ZNF562 | c.325C>G p.Q109E (on ENST00000453372 / NM_001130032.2; = p.Q37E on NM_017656.4) | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53333943; called by muse, mutect2, varscan2
- ZNF695 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV60586195; called by muse, mutect2
- ZP4 | c.1075T>A p.Y359N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100850567, COSV63913025; called by muse, mutect2, varscan2
- ZRANB3 | c.357T>G p.V119= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99922644; called by muse, mutect2, varscan2
- ALDH5A1 | c.727-1G>T p.X243_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MED12 | c.5890G>T p.V1964L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.184); called by muse, mutect2
- OCIAD2 | c.397dup p.T133Nfs*3 (on ENST00000508632 / NM_001014446.3; = p.P94Tfs*23 on NM_152398.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- PKP1 | c.1918_1920delinsTC p.V640Sfs*26 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by pindel, varscan2*
- RASSF10 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, varscan2
- ADAMTSL1 | c.2655C>A p.G885= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101001308; called by muse, mutect2, varscan2
- ARHGAP28 | c.1042C>T p.L348= (on ENST00000383472 / NM_001366230.1; = p.L189= on NM_001010000.3) | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV51646092; called by muse, mutect2, varscan2
- ATN1 | c.3279C>T p.P1093= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99980645; called by muse, mutect2, varscan2
- CCDC144A | c.120C>T p.Y40= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100501940; called by muse, mutect2, varscan2
- COPS7A | c.741T>C p.P247= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99976391; called by muse, mutect2
- CPAMD8 | c.822C>A p.P274= (on ENST00000651564; = p.P227= on NM_015692.5) | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV99358977; called by muse, mutect2, varscan2
- CYLD | c.1908C>A p.T636= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV61096290; called by muse, mutect2, varscan2
- DGKG | c.2052G>A p.R684= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99402462; called by muse, mutect2, varscan2
- DIAPH2 | c.2091G>T p.G697= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as COSV100230814; called by muse, mutect2, varscan2
- DNM3 | c.300G>A p.E100= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV62463909, COSV62469765; called by muse, mutect2
- ERAL1 | c.807C>A p.A269= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99650221; called by muse, mutect2, varscan2
- HSPB1 | c.510C>G p.P170= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs916533048, COSV99949145; called by muse, mutect2, varscan2
- JPH3 | c.2184G>A p.L728= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99412838; called by muse, mutect2
- LOX | c.477G>A p.P159= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs998690460, COSV99140594; called by muse, mutect2, varscan2
- MASP1 | c.99G>A p.S33= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs74784100; called by muse, mutect2, varscan2
- MUC16 | c.28185T>C p.T9395= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101198110, COSV67471318; called by muse, mutect2, varscan2
- MUC17 | c.4506C>A p.T1502= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100071617, COSV60280305; called by muse, mutect2
- MYO7B | c.6333A>T p.P2111= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100264177; called by muse, mutect2
- NDST2 | c.2613G>A p.S871= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs367975472; called by muse, mutect2, varscan2
- NR2C2 | c.1443C>T p.S481= (on ENST00000393102; = p.S500= on NM_003298.5) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100038270; called by muse, mutect2, varscan2
- OR7D4 | c.69G>T p.L23= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100432599; called by muse, mutect2, varscan2
- PALMD | c.1170G>A p.E390= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as rs1010962974, COSV99586146; called by muse, mutect2, varscan2
- PPP2R3B | c.1566C>T p.P522= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs773605704, COSV101180647; called by muse, mutect2, varscan2
- PRPS1L1 | c.459G>A p.K153= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs772224581, COSV101552913; called by muse, mutect2, varscan2
- PTH2 | c.18G>T p.V6= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99569530; called by muse, mutect2, varscan2
- RHBDF2 | c.2382C>T p.G794= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs960345978, COSV99166179; called by muse, mutect2, varscan2
- SIGLEC6 | c.570G>A p.L190= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs767508034, COSV100585158; called by muse, mutect2, varscan2
- TEX14 | c.975G>A p.V325= (on ENST00000240361 / NM_001201457.2; = p.V319= on NM_031272.5) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99541414; called by muse, mutect2, varscan2
- TTN | c.82530T>C p.T27510= (on ENST00000591111; = p.T20086= on NM_003319.4) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100594485; called by muse, mutect2, varscan2
- TUT4 | c.816G>A p.E272= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99931829; called by muse, mutect2, varscan2
- ZDBF2 | c.342T>C p.I114= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs766823426, COSV100984361; called by muse, mutect2, varscan2
- ZNF816 | c.405G>A p.L135= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs529254404, COSV54410345, COSV54412072; called by muse, mutect2, varscan2
- HDAC9 | c.2577+28T>A | Intron (SNP) | VAF 20/157 reads (13%) | catalogued as rs199995796; called by muse, mutect2, varscan2
- SENP1 | c.221-251G>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99136797; called by muse, mutect2, varscan2
- SPACA6 | c.-197G>T | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
